Somatic mutation profile of tumor specimen TCGA-EY-A1GW-01A (aliquot TCGA-EY-A1GW-01A-22D-A13L-09) from TCGA case TCGA-EY-A1GW, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 73.9 years (26,979 days).
Specimen TCGA-EY-A1GW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77adb0db-376f-4d75-af4f-52b7856660da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A1GW-10A (Blood Derived Normal), aliquot TCGA-EY-A1GW-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1669f683-d4bb-4ca5-a4bb-e91fe36517a2

The open-access MAF lists 51 somatic variants for this specimen: 46 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 35, Silent 5, Frame Shift Del 4, Frame Shift Ins 2, Splice Site 2, Nonsense Mutation 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 27/49 reads (55%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CDKN2A | c.130dup p.Y44Lfs*76 | Frame Shift Ins (INS) | VAF 19/27 reads (70%) | catalogued as COSV58682773, COSV58689669, COSV58711803, COSV58713131; called by mutect2, pindel, varscan2
- DAOA | c.202G>A p.G68S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs200951630, COSV61602376; called by muse, mutect2, varscan2
- DSCAML1 | c.1004G>A p.R335H (on ENST00000321322; = p.R275H on NM_020693.4) | Missense Mutation (SNP) | VAF 31/38 reads (82%) | SIFT tolerated (0.28); PolyPhen benign (0.043); catalogued as rs370860025; called by muse, mutect2, varscan2
- EPB41L5 | c.1446C>G p.D482E | Missense Mutation (SNP) | VAF 23/27 reads (85%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200443214, COSV99758895; called by muse, mutect2, varscan2
- HHIPL2 | c.46C>T p.R16W | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs757482859; called by muse, varscan2
- HS3ST5 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs780604705, COSV57133836; called by muse, mutect2, varscan2
- MAP2K4 | c.524G>A p.W175* | Nonsense Mutation (SNP) | VAF 17/25 reads (68%) | catalogued as COSV62259432; called by muse, mutect2, varscan2
- MYH11 | c.2006G>A p.R669H | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as rs760656490, COSV55552000; called by muse, mutect2, varscan2
- OR5T2 | c.93G>A p.M31I | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV100506933, COSV57588434; called by muse, mutect2, varscan2
- PTEN | c.371G>T p.C124F | Missense Mutation (SNP) | VAF 47/70 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM041823, CM110163, COSV64289150, COSV64290215, COSV64293195; called by muse, mutect2, varscan2
- PTEN | c.372T>G p.C124W | Missense Mutation (SNP) | VAF 47/70 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as CM110160; called by muse, mutect2, varscan2
- PTHLH | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV52367018; called by muse, mutect2, varscan2
- PTPDC1 | c.2011G>A p.A671T (on ENST00000375360 / NM_177995.3; = p.A723T on NM_152422.4) | Missense Mutation (SNP) | VAF 41/41 reads (100%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs375177766; called by muse, mutect2, varscan2
- THEMIS | c.1818del p.V607Yfs*2 | Frame Shift Del (DEL) | VAF 40/102 reads (39%) | catalogued as COSV64073057; called by mutect2, pindel, varscan2
- TSHZ3 | c.600C>A p.S200R | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53663226, COSV53665791; called by muse, mutect2, varscan2
- USP4 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as rs138851995, COSV55536580; called by muse, mutect2, varscan2
- UTS2R | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100493374; called by muse, mutect2
- ZBTB7B | c.398T>G p.V133G (on ENST00000292176; = p.V167G on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99420827; called by muse, mutect2
- ACOT6 | c.605T>C p.V202A | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CACNA1C | c.619C>A p.L207I | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- DMBT1 | c.2042del p.C681Sfs*45 | Frame Shift Del (DEL) | VAF 32/160 reads (20%) | called by mutect2, pindel, varscan2
- DNAH11 | c.9770_9773del p.N3257Mfs*11 | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | called by mutect2, pindel, varscan2
- EP400 | c.4636_4647del p.S1546_P1549del | In Frame Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- FRYL | c.3235C>T p.H1079Y | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.19); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- IFRD1 | c.906+2dup p.X302_splice | Splice Site (INS) | VAF 16/40 reads (40%) | called by mutect2, pindel, varscan2
- KCNT1 | c.1621G>T p.E541* (on ENST00000488444; = p.E560* on NM_020822.3) | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- KIR2DS4 | c.690A>C p.K230N | Missense Mutation (SNP) | VAF 87/201 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); called by muse, mutect2
- LHX6 | c.346G>C p.E116Q (on ENST00000373755 / NM_001242334.2; = p.E145Q on NM_014368.5) | Missense Mutation (SNP) | VAF 19/21 reads (90%) | SIFT tolerated (0.15); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- LIMA1 | c.583A>T p.N195Y | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- PIK3R1 | c.1742dup p.L581Ffs*21 (on ENST00000521381 / NM_181523.3; = p.L311Ffs*21 on NM_181504.4) | Frame Shift Ins (INS) | VAF 23/36 reads (64%) | called by mutect2, pindel, varscan2
- PPARA | c.296A>C p.N99T | Missense Mutation (SNP) | VAF 31/36 reads (86%) | SIFT tolerated (0.16); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- PTEN | c.79+1_79+9del p.X27_splice | Splice Site (DEL) | VAF 6/27 reads (22%) | called by mutect2, pindel
- QRICH1 | c.262A>G p.T88A | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- RALGAPB | c.697G>C p.V233L | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (1); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SLC13A1 | c.1776G>T p.E592D | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT tolerated (0.5); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SOX4 | c.247G>C p.D83H | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SPOCD1 | c.281_287del p.S94Wfs*19 | Frame Shift Del (DEL) | VAF 22/67 reads (33%) | called by mutect2, pindel, varscan2
- SULT1A1 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- TJP1 | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TULP1 | c.1429C>A p.L477I | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- UNC79 | c.2002G>A p.G668S (on ENST00000393151 / NM_001346218.2; = p.G491S on NM_020818.5) | Missense Mutation (SNP) | VAF 59/130 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZFYVE9 | c.1220T>A p.L407Q | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZGPAT | c.944A>T p.D315V | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2
- ZNF107 | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ZNF488 | c.307A>T p.T103S | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CLPTM1 | c.1179G>T p.V393= | Silent (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2
- OR5L2 | c.75C>A p.V25= | Silent (SNP) | VAF 25/84 reads (30%) | called by muse, mutect2, varscan2
- SCN9A | c.4977C>T p.A1659= (on ENST00000303354; = p.A1648= on NM_002977.3) | Silent (SNP) | VAF 50/61 reads (82%) | called by muse, mutect2, varscan2
- SLC9A6 | c.1764T>C p.D588= | Silent (SNP) | VAF 20/27 reads (74%) | catalogued as rs1397158891; called by muse, mutect2, varscan2
- TSPEAR | c.90C>T p.R30= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs374553699; called by muse, mutect2, varscan2
